Somatic mutation profile of tumor specimen TCGA-95-7947-01A (aliquot TCGA-95-7947-01A-11D-2184-08) from TCGA case TCGA-95-7947, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.8 years (24,752 days).
Specimen TCGA-95-7947-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5387a7a6-6882-476e-a57c-fffca53b11e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-95-7947-10A (Blood Derived Normal), aliquot TCGA-95-7947-10A-01D-2184-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0344b01e-7430-4200-81cb-d48a3a8998ac

The open-access MAF lists 593 somatic variants for this specimen: 449 protein-altering or splice-affecting, 136 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 396, Silent 136, Nonsense Mutation 24, Frame Shift Del 9, Splice Region 7, Frame Shift Ins 6, Splice Site 6, Intron 3, 5'Flank 3, 3'Flank 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 90/175 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.2091G>C p.L697F | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.923); catalogued as COSV62790803, COSV62791325; called by muse, mutect2, varscan2
- ABCB11 | c.280G>C p.D94H | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV55595275, COSV55596464, COSV99792434; called by muse, mutect2, varscan2
- ACSM4 | c.1741T>C p.*581Qext*17 | Nonstop Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as rs1030511087, COSV68068433; called by muse, mutect2, varscan2
- ACSM5 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 103/207 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); catalogued as COSV59373057; called by muse, mutect2, varscan2
- ADAMTS12 | c.454G>T p.V152F | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs777260765, COSV61269260; called by muse, mutect2, varscan2
- ADAMTS18 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1263485639, COSV51418888; called by muse, mutect2, varscan2
- ADAMTS9 | c.3040G>A p.D1014N | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV55785280; called by muse, mutect2, varscan2
- ADAMTSL3 | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as COSV54457185; called by muse, mutect2, varscan2
- ADGRA2 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372027558; called by muse, mutect2, varscan2
- ADGRL2 | c.3293G>C p.C1098S (on ENST00000370717 / NM_001366005.1; = p.C1085S on NM_012302.4) | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54668605, COSV54676131; called by muse, mutect2, varscan2
- ADGRL3 | c.3575del p.C1192Lfs*72 (on ENST00000506720 / NM_001322402.2; = p.C1124Lfs*72 on NM_015236.6) | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as COSV72232432; called by mutect2, pindel, varscan2
- AGTR2 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.85); PolyPhen benign (0.066); catalogued as COSV64156704; called by muse, mutect2, varscan2
- AHNAK | c.14488G>A p.A4830T | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs543343312, COSV57211202; called by muse, mutect2, varscan2
- AKAP6 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 24/92 reads (26%) | catalogued as COSV55221267; called by muse, mutect2, varscan2
- AKAP6 | c.3656G>A p.W1219* | Nonsense Mutation (SNP) | VAF 27/99 reads (27%) | catalogued as COSV55221277; called by muse, mutect2, varscan2
- ALDH8A1 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs533886052, COSV55642834; called by muse, varscan2
- ALMS1 | c.2552C>G p.P851R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV52514629; called by muse, varscan2
- ALMS1 | c.2686C>G p.Q896E | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs376834704; ClinVar: uncertain significance; called by muse, varscan2
- ALMS1 | c.11654A>G p.K3885R | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV52514654; called by muse, mutect2, varscan2
- ALOX12B | c.1711A>G p.I571V | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as COSV59874371; called by muse, mutect2, varscan2
- AMELY | c.361C>T p.Q121* (on ENST00000383036 / NM_001364814.1; = p.Q107* on NM_001143.1) | Nonsense Mutation (SNP) | VAF 64/86 reads (74%) | catalogued as COSV53095961; called by muse, mutect2, varscan2
- AMY2B | c.1342G>T p.D448Y | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs576493727, COSV63716087; called by muse, mutect2, varscan2
- ANK3 | c.2308G>A p.A770T | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55067975; called by muse, mutect2, varscan2
- ANO1 | c.671T>A p.F224Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV60286794; called by muse, mutect2, varscan2
- AOX1 | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65979734; called by muse, mutect2, varscan2
- AP3B2 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV55611533; called by muse, mutect2, varscan2
- APOA1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV52636107; called by muse, mutect2, varscan2
- APOL5 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV50767604; called by muse, mutect2, varscan2
- AREL1 | c.2159T>C p.V720A | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV62667093; called by muse, mutect2, varscan2
- ARHGAP30 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs750893517, COSV63516565; called by muse, varscan2
- ARHGAP45 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57432959, COSV57433788; called by muse, mutect2, varscan2
- ASAP1 | c.2803C>G p.P935A | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV63051468; called by muse, mutect2, varscan2
- ASXL2 | c.1382C>G p.S461* | Nonsense Mutation (SNP) | VAF 96/256 reads (38%) | catalogued as COSV55456432, COSV55462578; called by muse, mutect2, varscan2
- ATE1 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV56438903; called by muse, mutect2, varscan2
- ATP10B | c.2192C>G p.A731G | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100514627; called by muse, mutect2, varscan2
- BAZ1A | c.3266A>T p.Q1089L | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62411053; called by muse, mutect2, varscan2
- BCL9 | c.191G>T p.C64F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV52347151; called by muse, mutect2, varscan2
- BEND4 | c.1233del p.R412Dfs*47 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | catalogued as COSV72469288; called by mutect2, pindel, varscan2
- BICRAL | c.1477C>T p.Q493* | Nonsense Mutation (SNP) | VAF 42/151 reads (28%) | catalogued as COSV58407021; called by muse, mutect2, varscan2
- BOC | c.445G>C p.A149P | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.18); catalogued as COSV56354372; called by muse, mutect2, varscan2
- BPIFB3 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV64957656; called by muse, mutect2
- BRINP2 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV64177086, COSV64178707; called by muse, mutect2, varscan2
- BRSK1 | c.1716G>T p.Q572H | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV58668066; called by muse, mutect2, varscan2
- C12orf71 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as rs1377083454, COSV70282498; called by muse, mutect2, varscan2
- C16orf90 | c.361C>A p.P121T (on ENST00000399645 / NM_001353385.2; = p.P112T on NM_001080524.2) | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as COSV68714565; called by muse, mutect2, varscan2
- C2CD3 | c.3533G>T p.G1178V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV58095469; called by muse, mutect2, varscan2
- C2CD5 | c.1157A>T p.E386V | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV61725807; called by muse, mutect2, varscan2
- C3AR1 | c.1367C>G p.A456G | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.494); catalogued as COSV50820557, COSV99368186; called by muse, mutect2, varscan2
- C9 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747276372, COSV54678811; called by muse, mutect2, varscan2
- CADM3 | c.1154G>A p.G385D (on ENST00000368125 / NM_001127173.3; = p.G419D on NM_021189.5) | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63673587; called by muse, mutect2, varscan2
- CALCR | c.925G>C p.V309L (on ENST00000649521 / NM_001164737.2; = p.V293L on NM_001742.4) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as COSV64009810; called by muse, mutect2, varscan2
- CASR | c.2710G>A p.E904K (on ENST00000490131; = p.E981K on NM_000388.4) | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56139123; called by muse, mutect2, varscan2
- CATSPER1 | c.1689C>G p.L563= | Splice Region (SNP) | VAF 17/61 reads (28%) | catalogued as rs762021038, COSV56411915, COSV56412673; called by muse, mutect2, varscan2
- CAVIN2 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV58424810; called by muse, mutect2, varscan2
- CCDC17 | c.1834C>T p.H612Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.563); catalogued as COSV59647764; called by muse, mutect2, varscan2
- CCDC39 | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56488101; called by muse, mutect2, varscan2
- CCDC39 | c.414G>T p.W138C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.609); catalogued as COSV56488107; called by muse, mutect2, varscan2
- CCDC7 | c.3842C>T p.T1281I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.997); catalogued as COSV56546656; called by muse, mutect2, varscan2
- CCNE1 | c.1007T>C p.M336T | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.665); catalogued as COSV52905022; called by muse, mutect2, varscan2
- CCT8 | c.877A>T p.T293S | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV54504946; called by muse, mutect2, varscan2
- CCT8L2 | c.587del p.G196Afs*27 | Frame Shift Del (DEL) | VAF 101/172 reads (59%) | catalogued as COSV100743157; called by mutect2, pindel, varscan2
- CD22 | c.392G>C p.R131P | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV50050193, COSV50058335; called by muse, mutect2, varscan2
- CD5L | c.790G>C p.V264L | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV63822495; called by muse, mutect2, varscan2
- CDH9 | c.110T>A p.I37K | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99143075; called by muse, mutect2, varscan2
- CDK16 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs1422835444, COSV52092956; called by muse, mutect2, varscan2
- CDX4 | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs1246151225, COSV65171630, COSV65171752; called by muse, mutect2, varscan2
- CEACAM18 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67283517; called by muse, mutect2, varscan2
- CELSR3 | c.6311G>T p.G2104V | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50912089; called by muse, mutect2, varscan2
- CENPJ | c.1756G>C p.D586H | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV67883734; called by muse, mutect2, varscan2
- CEP128 | c.2726A>T p.K909M | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55382828; called by muse, mutect2, varscan2
- CFAP45 | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.023); catalogued as COSV63649974; called by muse, mutect2, varscan2
- CHD5 | c.4072G>T p.D1358Y | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52419522; called by muse, mutect2, varscan2
- CHD7 | c.2854G>A p.D952N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as COSV71112576; called by muse, mutect2, varscan2
- CHRND | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51323912; called by muse, mutect2, varscan2
- CKAP2L | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV56697084; called by muse, mutect2, varscan2
- CLCA1 | c.1680G>C p.K560N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV52329121, COSV99322726; called by muse, mutect2, varscan2
- CLSTN1 | c.2818G>A p.E940K (on ENST00000377298 / NM_001009566.3; = p.E930K on NM_014944.4) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as rs1002647679, COSV63127199; called by muse, varscan2
- CLVS1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.024); catalogued as rs1316816191, COSV57977827, COSV57979643; called by muse, mutect2, varscan2
- CNTN1 | c.1778C>T p.S593L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as rs267603460, COSV61642218; called by muse, mutect2, varscan2
- CNTN5 | c.236C>G p.P79R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); catalogued as rs1432462696, COSV54330503; called by muse, mutect2, varscan2
- CNTNAP1 | c.2624G>A p.W875* | Nonsense Mutation (SNP) | VAF 113/184 reads (61%) | catalogued as COSV52852183; called by muse, mutect2, varscan2
- COL11A1 | c.3416G>A p.S1139N | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV62189194; called by muse, mutect2, varscan2
- COL22A1 | c.2201C>A p.P734H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57330828; called by muse, mutect2, varscan2
- COL22A1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV57337822; called by muse, mutect2, varscan2
- COL6A6 | c.1093C>A p.L365M | Missense Mutation (SNP) | VAF 105/220 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV62030269; called by muse, mutect2, varscan2
- COPG1 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59115339; called by muse, mutect2, varscan2
- CSF3R | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV58968987; called by muse, mutect2, varscan2
- CSMD2 | c.2684C>T p.S895L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs774576659, COSV99588566; called by muse, mutect2, varscan2
- CYP2D6 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as COSV62244657; called by muse, mutect2, varscan2
- CYP7B1 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs989981846, COSV59592449; called by muse, mutect2, varscan2
- DCAF4L2 | c.853del p.L285Wfs*6 | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | catalogued as COSV60483562; called by mutect2, pindel, varscan2
- DDX27 | c.62T>G p.V21G | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs779809768, COSV65630331; called by muse, mutect2, varscan2
- DDX50 | c.2005G>C p.D669H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV65292832; called by muse, mutect2, varscan2
- DENND1C | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs779688426, COSV67374129; called by muse, mutect2, varscan2
- DHX40 | c.2250C>A p.D750E | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.011); catalogued as COSV52068757; called by muse, mutect2, varscan2
- DICER1 | c.4514C>T p.S1505F | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV58622405, COSV58623648; called by muse, mutect2, varscan2
- DIDO1 | c.1592C>T p.T531M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs768661117, COSV56623615; called by muse, mutect2, varscan2
- DNAH3 | c.1134G>T p.L378F | Missense Mutation (SNP) | VAF 104/226 reads (46%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.957); catalogued as COSV54534154; called by muse, mutect2, varscan2
- DPY19L1 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100204620; called by mutect2, varscan2
- DSCAM | c.4534G>C p.E1512Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs767997820, COSV68020067, COSV68031003; called by muse, mutect2, varscan2
- DSG4 | c.3021G>A p.M1007I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV57394140; called by muse, varscan2
- DST | c.20551A>G p.T6851A (on ENST00000361203 / NM_001374722.1; = p.T4548A on NM_015548.5) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.028); catalogued as COSV99754109; called by muse, mutect2, varscan2
- DYNC2H1 | c.10876G>A p.V3626M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as rs201852557; ClinVar: uncertain significance; called by mutect2, varscan2
- DYTN | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV71752497; called by muse, mutect2, varscan2
- DZIP3 | c.972G>T p.R324S | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV64312775; called by muse, mutect2, varscan2
- E2F1 | c.1311C>G p.F437L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV55777200; called by muse, varscan2
- EBF1 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58186155; called by muse, mutect2, varscan2
- EBF3 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV62477520; called by muse, mutect2, varscan2
- ECM2 | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 8/230 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV60741869; called by muse, mutect2
- EDNRB | c.997A>G p.I333V (on ENST00000377211 / NM_001201397.1; = p.I243V on NM_000115.5) | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV57525332; called by muse, mutect2, varscan2
- EDRF1 | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV61765000; called by muse, mutect2, varscan2
- EGFR | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV51819886, COSV51853292; called by muse, mutect2, varscan2
- EGFR | c.3155G>T p.R1052I | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV51819914; called by muse, varscan2
- EIF1AX | c.181A>C p.I61L | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV63309394; called by muse, varscan2
- EIF4E2 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV51472486; called by muse, mutect2, varscan2
- ELL | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV53213955; called by muse, mutect2, varscan2
- ELN | c.1252G>T p.A418S | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as rs142438174, COSV52712498; called by muse, mutect2, varscan2
- ERCC4 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV61312894, COSV61313009; called by muse, mutect2, varscan2
- ERO1A | c.465G>T p.W155C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67471632; called by muse, mutect2, varscan2
- EVX2 | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs757814311, COSV57964227; called by muse, mutect2, varscan2
- FBH1 | c.2374C>T p.Q792* (on ENST00000362091 / NM_178150.3; = p.Q843* on NM_032807.4) | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as COSV62983342; called by muse, mutect2, varscan2
- FBLL1 | c.738C>G p.F246L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV57924435; called by muse, mutect2, varscan2
- FBXO39 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58622395; called by muse, mutect2, varscan2
- FBXO5 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.06); catalogued as rs779399211, COSV57671218; called by muse, mutect2, varscan2
- FCRL4 | c.1107G>T p.Q369H | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.401); catalogued as COSV54860358; called by muse, mutect2, varscan2
- FIG4 | c.503G>T p.S168I | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57789049; called by muse, mutect2, varscan2
- FLG2 | c.5588G>C p.G1863A | Missense Mutation (SNP) | VAF 184/405 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV66170484; called by muse, mutect2, varscan2
- FLNC | c.7721C>A p.A2574D | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.315); catalogued as COSV57959519; called by muse, mutect2, varscan2
- FN1 | c.1537C>T p.Q513* | Nonsense Mutation (SNP) | VAF 58/189 reads (31%) | catalogued as COSV60557752; called by muse, mutect2, varscan2
- FRAS1 | c.4774C>T p.Q1592* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV53625923; called by muse, mutect2
- FRYL | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV51953115; called by muse, mutect2, varscan2
- GABBR2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); catalogued as COSV52311065; called by muse, mutect2, varscan2
- GABRG1 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.764); catalogued as COSV54957586; called by muse, mutect2, varscan2
- GATAD2B | c.954G>A p.M318I | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.775); catalogued as COSV64084879; called by muse, mutect2, varscan2
- GCNT1 | c.385G>T p.V129F | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1475504753, COSV65058127; called by muse, mutect2, varscan2
- GKAP1 | c.833A>C p.Q278P | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64487435; called by muse, mutect2, varscan2
- GLCCI1 | c.801C>G p.I267M | Missense Mutation (SNP) | VAF 96/146 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.295); catalogued as COSV56203333, COSV56203749; called by muse, mutect2, varscan2
- GLIS1 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.97); catalogued as COSV56551939; called by muse, mutect2, varscan2
- GLS2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV61737155, COSV61737803; called by muse, mutect2, varscan2
- GPR37 | c.663G>C p.Q221H | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV58258119; called by muse, mutect2, varscan2
- GPRC5B | c.264G>C p.E88D | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as COSV56027502; called by muse, varscan2
- GRAP | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52413792; called by muse, mutect2, varscan2
- GRB10 | c.1505A>T p.E502V (on ENST00000398812; = p.E456V on NM_001001549.3) | Missense Mutation (SNP) | VAF 81/345 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV100240188; called by muse, mutect2, varscan2
- GRB10 | c.1504G>A p.E502K (on ENST00000398812; = p.E456K on NM_001001549.3) | Missense Mutation (SNP) | VAF 78/340 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV100240192; called by muse, mutect2, varscan2
- GRID1 | c.1009A>G p.K337E | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV60039325; called by muse, mutect2, varscan2
- GYPC | c.107-2A>G p.X36_splice | Splice Site (SNP) | VAF 31/119 reads (26%) | catalogued as COSV52147419; called by muse, mutect2, varscan2
- H2AC12 | c.61C>G p.R21G | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); catalogued as COSV63617369, COSV63617773; called by muse, mutect2, varscan2
- HAO1 | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV66492807; called by muse, mutect2, varscan2
- HCN1 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57517608; called by muse, mutect2, varscan2
- HERC2 | c.13120G>T p.D4374Y | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV55334749; called by muse, mutect2, varscan2
- HIPK4 | c.1733G>T p.C578F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99396537; called by muse, mutect2
- HLA-A | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs199474387, COSV100954343; called by muse, varscan2
- HOXD3 | c.561G>C p.K187N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as COSV50882496; called by muse, mutect2, varscan2
- IFTAP | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV57558608; called by muse, mutect2, varscan2
- IGKV3-7 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as rs369766180; called by muse, mutect2, varscan2
- IKBKB | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779165425, COSV60595796; called by muse, mutect2, varscan2
- IL18RAP | c.155A>T p.Q52L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV51827384; called by muse, mutect2, varscan2
- IL23R | c.89G>T p.C30F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61375189; called by muse, mutect2, varscan2
- INTS8 | c.2458G>C p.E820Q | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.991); catalogued as rs1410151071, COSV58251952; called by muse, mutect2, varscan2
- IPMK | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs999405339, COSV61703817; called by muse, mutect2, varscan2
- IPO4 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 38/127 reads (30%) | catalogued as COSV55780829; called by muse, mutect2, varscan2
- IRF4 | c.915G>C p.E305D | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV66705629; called by muse, mutect2, varscan2
- ITGAM | c.2863C>T p.Q955* (on ENST00000648685 / NM_001145808.2; = p.Q954* on NM_000632.4) | Nonsense Mutation (SNP) | VAF 25/39 reads (64%) | catalogued as COSV54939410; called by muse, mutect2, varscan2
- JAG1 | c.563A>G p.D188G | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV54759266; called by muse, mutect2, varscan2
- KAT14 | c.2052C>G p.I684M | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV66608427; called by muse, mutect2, varscan2
- KATNIP | c.3572C>T p.P1191L | Missense Mutation (SNP) | VAF 91/182 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as COSV55185516; called by muse, mutect2, varscan2
- KCNB1 | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 212/444 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.748); catalogued as COSV100870424, COSV65569506; called by muse, mutect2, varscan2
- KCNJ2 | c.443G>T p.R148I | Missense Mutation (SNP) | VAF 91/130 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54662620; called by muse, mutect2, varscan2
- KCNK13 | c.335-2A>G p.X112_splice | Splice Site (SNP) | VAF 26/91 reads (29%) | catalogued as COSV56414159; called by muse, mutect2, varscan2
- KEAP1 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV50260519; called by muse, mutect2, varscan2
- KIAA0586 | c.3367A>G p.I1123V (on ENST00000619416 / NM_001244190.2; = p.I1062V on NM_014749.5) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV54178660; called by muse, mutect2, varscan2
- KIAA1522 | c.2950C>G p.R984G (on ENST00000373480 / NM_001198972.2; = p.R1043G on NM_020888.3) | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV53866023; called by muse, mutect2, varscan2
- KIAA1549 | c.3974G>T p.R1325L | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54319747, COSV99650435; called by muse, mutect2, varscan2
- KIF4B | c.1292A>T p.N431I | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV70530315; called by muse, mutect2, varscan2
- KIF5B | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56651665, COSV56654238; called by muse, mutect2, varscan2
- KISS1R | c.239A>G p.Y80C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1228617980, COSV52257716; called by muse, mutect2, varscan2
- KLHL4 | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100909405; called by muse, mutect2, varscan2
- KLHL5 | c.522-2A>G p.X174_splice | Splice Site (SNP) | VAF 22/80 reads (28%) | catalogued as COSV54676266; called by mutect2, varscan2
- KRT25 | c.695C>A p.A232D | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV56445646, COSV56446578; called by muse, mutect2, varscan2
- KRT75 | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52873908; called by muse, mutect2, varscan2
- KRTAP10-8 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 108/404 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs782003448, COSV58166759; called by muse, mutect2, varscan2
- KRTAP13-1 | c.143T>A p.L48Q | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV62663798; called by muse, mutect2, varscan2
- KRTAP4-12 | c.464G>T p.C155F | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV67458069; called by muse, mutect2
- LAIR2 | c.417G>A p.G139= | Splice Region (SNP) | VAF 24/111 reads (22%) | catalogued as rs749752494, COSV56621191, COSV56621943; called by muse, mutect2, varscan2
- LARP4B | c.1385C>T p.T462I | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV60222283; called by muse, mutect2, varscan2
- LCMT1 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66726006; called by muse, mutect2, varscan2
- LEFTY1 | c.154G>T p.V52F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV55283533; called by muse, mutect2
- LGALS12 | c.865A>T p.S289C | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55371248; called by muse, mutect2, varscan2
- LGALS14 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62372953, COSV62373408; called by muse, mutect2, varscan2
- LIPG | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV54297019; called by muse, mutect2, varscan2
- LMTK2 | c.3097G>A p.E1033K | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51999409; called by muse, mutect2, varscan2
- LRFN2 | c.697C>A p.P233T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as COSV57830526; called by muse, mutect2, varscan2
- LRP1 | c.4564C>T p.P1522S | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54517518; called by muse, mutect2, varscan2
- LRP10 | c.52C>G p.P18A | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs748879596, COSV62078571; called by muse, mutect2, varscan2
- LRP5 | c.3511G>T p.D1171Y | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53719015, COSV53722341; called by muse, mutect2, varscan2
- LRRC23 | c.205C>G p.H69D | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV50391293, COSV50392466; called by muse, mutect2, varscan2
- LRRC55 | c.208C>A p.L70I | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73006725; called by muse, mutect2, varscan2
- LRRC66 | c.2559G>T p.Q853H | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV58635124; called by muse, mutect2, varscan2
- LRRCC1 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV64484252; called by muse, mutect2, varscan2
- MACF1 | c.16160A>C p.Q5387P (on ENST00000372915; = p.Q3320P on NM_012090.5) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV57131190; called by muse, mutect2, varscan2
- MACROD2 | c.390C>G p.I130M | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54013374; called by muse, mutect2, varscan2
- MAP4K3 | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV55715113; called by muse, mutect2, varscan2
- MARVELD2 | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV57781420; called by muse, mutect2, varscan2
- MBD5 | c.1362G>T p.E454D | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68698197; called by muse, mutect2, varscan2
- MDGA2 | c.2374T>A p.F792I (on ENST00000399232 / NM_001113498.2; = p.F494I on NM_182830.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV62102486; called by muse, mutect2, varscan2
- MDN1 | c.3970G>C p.E1324Q | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV65524810; called by muse, mutect2, varscan2
- METTL22 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV50838101, COSV50839029; called by muse, mutect2, varscan2
- MFAP1 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 81/233 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51039673; called by muse, mutect2, varscan2
- MGAT5 | c.484T>A p.W162R | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56098424; called by muse, mutect2, varscan2
- MLXIP | c.2387C>T p.S796F | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.38); catalogued as COSV59836578; called by muse, mutect2, varscan2
- MMP21 | c.945C>G p.D315E | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); catalogued as rs760595351, COSV64289684; called by muse, mutect2, varscan2
- MNX1 | c.850C>G p.Q284E | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53318602; called by muse, mutect2, varscan2
- MPO | c.442C>A p.Q148K | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV56565955, COSV99833102; called by muse, mutect2, varscan2
- MPP6 | c.613A>T p.I205F | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56040347; called by muse, mutect2, varscan2
- MRGBP | c.147C>T p.V49= | Splice Region (SNP) | VAF 7/17 reads (41%) | catalogued as COSV65111593; called by muse, mutect2, varscan2
- MROH2B | c.3093G>A p.M1031I | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.037); catalogued as COSV68186567; called by muse, mutect2, varscan2
- MROH9 | c.1541T>A p.V514E | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63012314; called by muse, mutect2, varscan2
- MRPL22 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV54558900; called by muse, varscan2
- MUC16 | c.43063G>T p.D14355Y | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.991); catalogued as rs776560450, COSV66691571, COSV66694479; called by muse, mutect2, varscan2
- MUC16 | c.25396C>G p.Q8466E | Missense Mutation (SNP) | VAF 64/226 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.629); catalogued as COSV67441157, COSV67478365; called by muse, mutect2, varscan2
- MYH15 | c.4459C>G p.Q1487E | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV56314399; called by muse, mutect2, varscan2
- MYH2 | c.4815C>G p.S1605R | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV55442414; called by muse, mutect2, varscan2
- MYH7B | c.5297C>T p.S1766L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs781351049, COSV52681917; called by muse, mutect2
- MYL5 | c.261G>T p.M87I | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59141039; called by muse, mutect2, varscan2
- MYO15A | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52760419; called by muse, mutect2, varscan2
- MYPN | c.1630C>A p.L544I | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0.154); catalogued as COSV62735659; called by muse, mutect2, varscan2
- NALCN | c.4669G>C p.E1557Q | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1434672101, COSV51948617; called by muse, mutect2, varscan2
- NBEA | c.6045A>C p.R2015S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV59800888; called by muse, mutect2, varscan2
- NBEAL1 | c.7942G>A p.D2648N | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV68916423; called by muse, mutect2, varscan2
- NDRG2 | c.229T>G p.S77A (on ENST00000298687 / NM_001354570.1; = p.S63A on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.341); catalogued as COSV53873100; called by muse, mutect2, varscan2
- NFE2L3 | c.1304C>G p.S435C | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV50231756; called by muse, mutect2, varscan2
- NLRP12 | c.959C>A p.T320K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.809); catalogued as COSV60750393; called by muse, mutect2, varscan2
- NLRP14 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.548); catalogued as COSV55069399; called by muse, mutect2, varscan2
- NLRP7 | c.2323C>A p.P775T (on ENST00000340844 / NM_206828.3; = p.P747T on NM_139176.3) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs555863660, COSV100052257; called by muse, mutect2, varscan2
- NMD3 | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV63618897; called by muse, mutect2, varscan2
- NOMO2 | c.1916G>C p.R639P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.67); catalogued as COSV100395633; called by mutect2, varscan2
- NOMO2 | c.1322C>G p.S441C | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV57917205; called by muse, mutect2, varscan2
- NPAS3 | c.1153+1G>T p.X385_splice (on ENST00000356141 / NM_001164749.2; = p.X353_splice on NM_022123.3) | Splice Site (SNP) | VAF 23/73 reads (32%) | catalogued as COSV60845472; called by muse, mutect2, varscan2
- NR5A2 | c.1228C>A p.Q410K (on ENST00000367362 / NM_205860.3; = p.Q364K on NM_003822.5) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs751984795, COSV52646597; called by muse, mutect2, varscan2
- OBI1 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV56146313; called by muse, mutect2, varscan2
- OGDHL | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV65103511; called by muse, mutect2, varscan2
- OLFM1 | c.1392G>A p.W464* (on ENST00000371793 / NM_001282611.2; = p.W446* on NM_014279.5) | Nonsense Mutation (SNP) | VAF 39/218 reads (18%) | catalogued as COSV53280300; called by muse, mutect2, varscan2
- OR10A2 | c.632C>A p.A211D | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV56299890; called by muse, mutect2, varscan2
- OR10Q1 | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57471153; called by muse, mutect2, varscan2
- OR10T2 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs769556851, COSV57782253; called by muse, mutect2, varscan2
- OR2B6 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV55129314; called by muse, mutect2, varscan2
- OR2F2 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 38/152 reads (25%) | catalogued as rs185106716, COSV101283805; called by muse, mutect2, varscan2
- OR2G2 | c.575G>T p.C192F | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756795272, COSV60739995, COSV60742785; called by muse, mutect2, varscan2
- OR4A16 | c.412G>T p.V138F | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.286); catalogued as rs1423418518, COSV100125145; called by muse, mutect2, varscan2
- OR4A5 | c.194C>A p.S65* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | catalogued as rs1232773653, COSV100157123, COSV60523421; called by muse, mutect2, varscan2
- OR51F1 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs1176887374, COSV58580185; called by muse, mutect2, varscan2
- OR5AS1 | c.809C>A p.T270N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as COSV57982420; called by muse, mutect2, varscan2
- OR5D13 | c.459G>T p.W153C | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.464); catalogued as COSV62334467; called by muse, mutect2, varscan2
- OR5J2 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56621263; called by muse, mutect2, varscan2
- OR6Y1 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV56928014, COSV56930171; called by muse, mutect2, varscan2
- OR8B8 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV60145073; called by muse, mutect2, varscan2
- OR8G5 | c.419C>A p.A140D | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV100422354, COSV58380902; called by muse, mutect2
- OR8G5 | c.421T>G p.C141G | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as COSV100422355; called by muse, mutect2
- OR9Q2 | c.133A>G p.M45V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV61112258; called by muse, mutect2, varscan2
- OTUD6A | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.386); catalogued as COSV57973887; called by muse, mutect2, varscan2
- OVCH2 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV71952949; called by muse, mutect2, varscan2
- PAF1 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.017); catalogued as COSV55393017, COSV55395127; called by muse, mutect2, varscan2
- PAH | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs62508679, CM000549, CM981451, COSV61018368; ClinVar: not provided; called by muse, mutect2, varscan2
- PAICS | c.525A>G p.I175M | Missense Mutation (SNP) | VAF 5/13 reads (38%) | PolyPhen probably damaging (0.943); catalogued as COSV51709335; called by muse, mutect2, varscan2
- PAPPA2 | c.2224T>C p.Y742H | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62781685; called by muse, mutect2, varscan2
- PBDC1 | c.307C>G p.P103A | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.714); catalogued as COSV64895988; called by muse, varscan2
- PCDH1 | c.3233G>T p.R1078L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV54612099; called by muse, mutect2, varscan2
- PCDH15 | c.4049G>A p.R1350H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs752356781, COSV57265804, COSV57366433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA2 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV65368823; called by muse, mutect2, varscan2
- PCDHA7 | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.058); catalogued as COSV65338585; called by muse, mutect2, varscan2
- PCDHA8 | c.1925C>G p.S642C | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as rs1554139882, COSV65324074, COSV65326711; called by muse, mutect2, varscan2
- PCDHAC1 | c.2861G>T p.G954V | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53858730; called by muse, mutect2, varscan2
- PCDHB7 | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.698); catalogued as rs1554279889, COSV50790169; called by muse, mutect2, varscan2
- PCDHB8 | c.1931T>A p.L644Q | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.192); catalogued as COSV50790170; called by muse, mutect2, varscan2
- PCDHGB2 | c.1490A>T p.K497M | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV53983649, COSV54016794; called by muse, mutect2, varscan2
- PCGF2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as rs779878626; called by muse, mutect2, varscan2
- PDCD7 | c.1332C>T p.I444= | Splice Region (SNP) | VAF 14/41 reads (34%) | catalogued as COSV52600901; called by muse, mutect2, varscan2
- PDCL2 | c.106C>A p.R36S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.048); catalogued as COSV55259804, COSV55261512; called by muse, mutect2, varscan2
- PDE3A | c.658G>C p.A220P | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as COSV62969575, COSV62977117; called by muse, mutect2, varscan2
- PDE6B | c.1014G>T p.W338C | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV55328217; called by muse, mutect2, varscan2
- PDZRN3 | c.2294G>T p.R765L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55206860; called by muse, mutect2, varscan2
- PHETA2 | c.82G>C p.G28R | Missense Mutation (SNP) | VAF 89/138 reads (64%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.484); catalogued as COSV58791152; called by muse, mutect2, varscan2
- PHF14 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.933); catalogued as COSV68854967, COSV68856132; called by muse, mutect2, varscan2
- PHIP | c.4375G>A p.E1459K | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.98); catalogued as COSV51507054; called by muse, mutect2, varscan2
- PHYH | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.312); catalogued as COSV53816808; called by muse, mutect2, varscan2
- PIF1 | c.1677C>A p.G559= | Splice Region (SNP) | VAF 13/52 reads (25%) | catalogued as COSV51423180; called by muse, mutect2, varscan2
- PIH1D2 | c.573C>G p.S191R | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.335); catalogued as COSV54775913; called by muse, mutect2
- PIK3AP1 | c.1919C>T p.S640L | Missense Mutation (SNP) | VAF 88/245 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs763855438, COSV59534391; called by muse, mutect2, varscan2
- PIK3C3 | c.2303G>T p.R768L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV56281596, COSV56282714; called by muse, mutect2, varscan2
- PLCB3 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV54190221; called by muse, mutect2, varscan2
- PLCB3 | c.3291C>G p.I1097M | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.324); catalogued as COSV54190227; called by muse, mutect2, varscan2
- PLSCR5 | c.764C>G p.A255G | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71649120; called by muse, mutect2, varscan2
- PLVAP | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99391584, COSV99391754; called by muse, mutect2, varscan2
- PLVAP | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370989890, COSV53086432; called by muse, mutect2, varscan2
- PLXNC1 | c.2736C>G p.I912M | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.466); catalogued as COSV51578674; called by muse, mutect2, varscan2
- PNLIPRP2 | c.335T>A p.M112K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV53944752; called by muse, mutect2, varscan2
- POC1A | c.1123C>G p.Q375E | Missense Mutation (SNP) | VAF 82/162 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.251); catalogued as COSV56592369; called by muse, mutect2, varscan2
- POLA1 | c.2683C>G p.Q895E | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV66888383; called by muse, mutect2, varscan2
- POU6F2 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.152); catalogued as rs1377034885, COSV68876998; called by muse, mutect2, varscan2
- PPFIBP2 | c.1453C>A p.P485T | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.448); catalogued as COSV55079346; called by muse, mutect2, varscan2
- PPP1R1A | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as rs369965740, COSV54494203; called by muse, mutect2, varscan2
- PPP1R3A | c.3106C>A p.Q1036K | Missense Mutation (SNP) | VAF 74/286 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs761016783, COSV52884317, COSV52886792; called by muse, mutect2, varscan2
- PRKD2 | c.1408G>C p.V470L | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV52188037; called by muse, mutect2, varscan2
- PRKG2 | c.55G>T p.G19W | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as COSV52327648; called by muse, mutect2, varscan2
- PRMT3 | c.1139T>C p.I380T | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV58178631; called by muse, mutect2, varscan2
- PRTG | c.1942A>T p.I648F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV66838996; called by muse, mutect2, varscan2
- PTCHD4 | c.1834G>T p.A612S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.896); catalogued as rs754898461, COSV59790362; called by muse, mutect2, varscan2
- PTK7 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as rs755117231, COSV57849861; called by muse, mutect2, varscan2
- PTX4 | c.1186C>T p.P396S (on ENST00000447419 / NM_001328608.2; = p.P391S on NM_001013658.1) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV53516867; called by muse, mutect2, varscan2
- PXDN | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs760063762, COSV53239902; called by muse, mutect2, varscan2
- RAB21 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54229286; called by muse, mutect2, varscan2
- RAI2 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 91/131 reads (69%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58965311; called by muse, mutect2, varscan2
- RANBP6 | c.2770G>C p.D924H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as COSV52390348; called by muse, mutect2, varscan2
- RBM14 | c.1493A>G p.Y498C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs144272368; called by muse, mutect2, varscan2
- RBM34 | c.18G>A p.M6I | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as rs370358826; called by muse, mutect2, varscan2
- REC114 | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV58523454; called by muse, mutect2, varscan2
- RFX5 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 104/221 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as COSV51839844, COSV51840184; called by muse, mutect2, varscan2
- RHOJ | c.232G>T p.G78* | Nonsense Mutation (SNP) | VAF 21/100 reads (21%) | catalogued as COSV100370200; called by muse, mutect2, varscan2
- RHOJ | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100370203; called by muse, varscan2
- RHOQ | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as COSV53190657; called by muse, mutect2, varscan2
- RNF31 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV53760426, COSV99396274; called by muse, mutect2, varscan2
- RNGTT | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55655286, COSV55659995; called by muse, mutect2, varscan2
- RPH3A | c.1229A>G p.Q410R (on ENST00000389385 / NM_001143854.2; = p.Q406R on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs775845098, COSV66992028; called by muse, mutect2, varscan2
- RSPO2 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs765464784, COSV52649079; called by muse, mutect2, varscan2
- RYR3 | c.1706G>T p.S569I | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66799566; called by muse, mutect2, varscan2
- SALL1 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV51752910, COSV51760752; called by muse, mutect2, varscan2
- SAP30L | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51737869; called by muse, mutect2, varscan2
- SART1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV100408963; called by muse, mutect2, varscan2
- SERGEF | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs747606267, COSV56385136; called by muse, mutect2
- SI | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV52288275; called by muse, mutect2, varscan2
- SIRPG | c.786G>T p.R262S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.045); catalogued as COSV53808626, COSV99403373; called by muse, mutect2, varscan2
- SLAMF8 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 209/443 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV56989145; called by muse, mutect2, varscan2
- SLC25A40 | c.758C>G p.T253S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62020857; called by muse, mutect2, varscan2
- SLC25A40 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100353636, COSV62019845; called by muse, mutect2, varscan2
- SLC35G3 | c.292C>G p.P98A | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as COSV52011931; called by muse, mutect2, varscan2
- SLC44A3 | c.230C>A p.S77Y (on ENST00000271227 / NM_001114106.3; = p.S29Y on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV54731813; called by muse, mutect2, varscan2
- SLC4A8 | c.1730T>C p.L577P | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV60655374; called by muse, varscan2
- SLC4A8 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV60655396; called by muse, varscan2
- SLC9A4 | c.2331G>T p.W777C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV54836360; called by muse, mutect2, varscan2
- SLITRK1 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV65676477; called by muse, mutect2, varscan2
- SLTM | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as COSV51055603; called by muse, mutect2, varscan2
- SMARCD1 | c.839T>A p.V280E | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67412548; called by muse, mutect2, varscan2
- SMARCD3 | c.560A>C p.E187A (on ENST00000262188 / NM_001003801.2; = p.E174A on NM_003078.4) | Missense Mutation (SNP) | VAF 79/142 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV50393878; called by muse, mutect2, varscan2
- SMC3 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62421101; called by muse, mutect2, varscan2
- SND1 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as rs1277276563, COSV61244487; called by muse, mutect2, varscan2
- SNTG2 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57994220; called by muse, mutect2, varscan2
- SOHLH1 | c.554C>G p.A185G | Missense Mutation (SNP) | VAF 116/152 reads (76%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV53681340, COSV53682776; called by muse, mutect2, varscan2
- SP4 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 62/376 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.354); catalogued as COSV56024561; called by muse, mutect2, varscan2
- SPATA16 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 141/340 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63531079; called by muse, mutect2, varscan2
- SPTB | c.5065A>T p.M1689L | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV67633344; called by muse, mutect2, varscan2
- SPTB | c.3205G>A p.D1069N | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV67633352; called by muse, mutect2, varscan2
- SPTLC1 | c.138A>C p.L46F | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV52765180; called by muse, varscan2
- SRP9 | c.181A>G p.K61E | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59159356; called by muse, mutect2, varscan2
- STC2 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as COSV54180915; called by muse, mutect2, varscan2
- STPG2 | c.1085A>T p.Y362F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.139); catalogued as COSV54808006; called by muse, mutect2, varscan2
- SUCO | c.3373G>C p.E1125Q | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV55268038; called by muse, mutect2, varscan2
- SUSD6 | c.123G>T p.V41= | Splice Region (SNP) | VAF 49/204 reads (24%) | catalogued as COSV61365921; called by muse, mutect2
- SUSD6 | c.125G>T p.C42F | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs1295987687, COSV61365928; called by muse, mutect2
- SWT1 | c.571A>T p.N191Y | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62256965; called by muse, mutect2, varscan2
- SYF2 | c.705G>C p.Q235H | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV52573929; called by muse, mutect2, varscan2
- SYNCRIP | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62288552, COSV62289513; called by muse, mutect2, varscan2
- SYNE2 | c.1630G>C p.E544Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV59958080; called by muse, mutect2, varscan2
- SYT7 | c.398G>C p.R133P | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as COSV55657360, COSV99801047; called by muse, mutect2, varscan2
- TACC2 | c.6170C>T p.S2057L (on ENST00000334433; = p.S135L on NM_006997.4) | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV53284603; called by muse, mutect2, varscan2
- TARBP1 | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV50191775; called by muse, mutect2, varscan2
- TBATA | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54720092; called by muse, mutect2, varscan2
- TCL1A | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV101268457; called by muse, mutect2, varscan2
- TCOF1 | c.2630G>T p.S877I (on ENST00000377797 / NM_001135243.1; = p.S800I on NM_000356.4) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.418); catalogued as COSV60350830; called by muse, mutect2, varscan2
- TCTN2 | c.1987G>T p.E663* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV57633766; called by muse, mutect2, varscan2
- TDRD1 | c.3260C>T p.S1087F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV52592893; called by muse, mutect2, varscan2
- TEX55 | c.1442G>C p.R481P | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.299); catalogued as COSV55211722; called by muse, mutect2, varscan2
- TFB1M | c.547-2A>G p.X183_splice | Splice Site (SNP) | VAF 11/37 reads (30%) | catalogued as COSV65699530; called by muse, mutect2, varscan2
- THRA | c.484C>G p.P162A | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV52844618; called by muse, mutect2, varscan2
- TMCO2 | c.89dup p.L30Ffs*5 | Frame Shift Ins (INS) | VAF 53/255 reads (21%) | catalogued as rs761324353; called by mutect2, pindel, varscan2
- TMEM145 | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 66/179 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56626340, COSV99040769; called by muse, mutect2, varscan2
- TMEM260 | c.878G>C p.R293T | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV55100918; called by muse, mutect2, varscan2
- TMEM39A | c.18G>C p.R6S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59900964; called by muse, mutect2, varscan2
- TMEM94 | c.2968A>G p.M990V | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1567973952, COSV58597774; called by muse, mutect2, varscan2
- TMPRSS15 | c.1836G>T p.M612I | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as COSV53043255; called by muse, mutect2, varscan2
- TMPRSS7 | c.1093T>A p.C365S (on ENST00000452346; = p.C239S on NM_001042575.2) | Missense Mutation (SNP) | VAF 95/398 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV69981520; called by muse, mutect2, varscan2
- TNC | c.1826G>A p.C609Y | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243984560, COSV60787064; called by muse, mutect2, varscan2
- TNR | c.2704C>A p.Q902K | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV54898609; called by muse, mutect2, varscan2
- TNXB | c.6490G>T p.D2164Y (on ENST00000647633; = p.D1917Y on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100926619, COSV64483036, COSV64490962; called by muse, mutect2, varscan2
- TPI1 | c.570T>C p.D190= (on ENST00000229270; = p.D153= on NM_000365.6) | Splice Region (SNP) | VAF 75/234 reads (32%) | catalogued as COSV51290275; called by muse, mutect2, varscan2
- TPPP2 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as rs775584852, COSV58795185; called by muse, mutect2, varscan2
- TRAF5 | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV54823552; called by muse, mutect2, varscan2
- TRDJ3 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as rs1407383367; called by muse, mutect2, varscan2
- TRIM29 | c.1546G>T p.V516F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV59281310; called by muse, mutect2, varscan2
- TRPC6 | c.1701G>T p.L567F | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60257599; called by muse, mutect2, varscan2
- TTC12 | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV59098772; called by muse, mutect2, varscan2
- TTN | c.75274G>T p.V25092L (on ENST00000591111; = p.V17668L on NM_003319.4) | Missense Mutation (SNP) | VAF 26/97 reads (27%) | PolyPhen benign (0.071); catalogued as COSV60180245; called by muse, mutect2, varscan2
- TXLNB | c.405G>T p.K135N | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs532444744, COSV64443771; called by muse, mutect2, varscan2
- UBAP1 | c.346C>G p.P116A | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.292); catalogued as COSV52660069; called by muse, mutect2, varscan2
- UBAP1 | c.1040C>G p.S347C | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.723); catalogued as COSV52660078; called by muse, mutect2, varscan2
- UNC5D | c.1833C>G p.I611M | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as COSV54811377; called by muse, mutect2, varscan2
- UPF1 | c.2794A>G p.N932D (on ENST00000599848 / NM_001297549.2; = p.N921D on NM_002911.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV99439257; called by muse, mutect2, varscan2
- USH2A | c.7883C>A p.P2628Q | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.867); catalogued as CD095927, COSV100233043, COSV56397392; called by muse, mutect2, varscan2
- USO1 | c.2277G>C p.M759I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV53708326; called by muse, mutect2, varscan2
- USP13 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.642); catalogued as COSV55867698, COSV55869826; called by muse, mutect2, varscan2
- USP34 | c.10327A>G p.R3443G | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV63725399; called by muse, mutect2, varscan2
- USP37 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV51445058; called by muse, mutect2, varscan2
- VCAM1 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54120453; called by muse, mutect2, varscan2
- VEZF1 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.899); catalogued as COSV51969388; called by muse, varscan2
- VIL1 | c.1543A>G p.T515A | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV50291346; called by muse, mutect2, varscan2
- VIPR2 | c.651C>A p.F217L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51110612; called by muse, mutect2, varscan2
- VIRMA | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as COSV52587777; called by muse, mutect2, varscan2
- VRK3 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs200821018, COSV100371852, COSV57466628; called by muse, mutect2, varscan2
- WDFY3 | c.5172G>T p.K1724N | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV55706973; called by muse, mutect2, varscan2
- WDFY3 | c.2354A>T p.E785V | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as COSV55706989; called by muse, mutect2, varscan2
- WDR77 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV52385682; called by muse, mutect2, varscan2
- WFIKKN2 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as rs1218772738, COSV60959425; called by muse, mutect2, varscan2
- XAGE3 | c.81+2T>A p.X27_splice | Splice Site (SNP) | VAF 29/46 reads (63%) | catalogued as COSV60569722; called by muse, mutect2, varscan2
- XG | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs769301242, COSV101150947, COSV66985860; called by muse, mutect2, varscan2
- XIRP1 | c.4397G>A p.R1466K | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.05); catalogued as COSV100453556, COSV61138834, COSV61139556; called by muse, mutect2, varscan2
- ZBED9 | c.3024G>C p.M1008I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV71729185, COSV71729588; called by muse, mutect2, varscan2
- ZC3H12A | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs753751128, COSV66103845; called by muse, mutect2, varscan2
- ZC3H12B | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV59049835; called by muse, mutect2, varscan2
- ZFHX4 | c.1020A>C p.K340N | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.691); catalogued as COSV50682756, COSV50970085, COSV51469134; called by muse, mutect2, varscan2
- ZFYVE26 | c.7120G>A p.A2374T | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs748405235, COSV61330785; called by muse, mutect2, varscan2
- ZNF280B | c.1017G>T p.W339C | Missense Mutation (SNP) | VAF 93/129 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100840239; called by muse, mutect2, varscan2
- ZNF280B | c.1016G>T p.W339L | Missense Mutation (SNP) | VAF 93/129 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV100840241; called by muse, mutect2, varscan2
- ZNF407 | c.845A>G p.Q282R | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV55260145; called by muse, mutect2, varscan2
- ZNF536 | c.2606A>T p.H869L | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV62828311; called by muse, mutect2, varscan2
- ZNF599 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV61395498; called by muse, mutect2, varscan2
- ZNF675 | c.1240C>T p.H414Y | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63096592; called by muse, mutect2, varscan2
- ZNF711 | c.1781A>G p.H594R | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); catalogued as rs1049891811, COSV52156555; called by muse, mutect2
- ZNF765 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV67182893; called by muse, mutect2, varscan2
- ZNF768 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV53224243; called by muse, mutect2, varscan2
- ZNF91 | c.3401A>T p.Y1134F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV56088013; called by muse, mutect2, varscan2
- ZNF93 | c.4G>T p.G2* | Nonsense Mutation (SNP) | VAF 47/210 reads (22%) | catalogued as COSV59376772; called by muse, mutect2, varscan2
- ZPLD1 | c.803G>A p.R268Q (on ENST00000466937 / NM_001329788.1; = p.R284Q on NM_175056.2) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as rs764415767, COSV60354760; called by muse, mutect2, varscan2
- AP5B1 | c.1735del p.V579Sfs*10 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- ASPM | c.10142del p.K3381Rfs*32 | Frame Shift Del (DEL) | VAF 74/146 reads (51%) | called by mutect2, pindel*, varscan2
- CCNJL | c.667del p.R223Afs*15 | Frame Shift Del (DEL) | VAF 19/135 reads (14%) | called by pindel, varscan2
- CCNJL | c.661T>G p.C221G | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); called by muse, varscan2
- CERS3 | c.181dup p.A61Gfs*11 | Frame Shift Ins (INS) | VAF 19/63 reads (30%) | called by mutect2, pindel, varscan2
- CUEDC2 | c.31dup p.L11Pfs*19 | Frame Shift Ins (INS) | VAF 23/96 reads (24%) | called by mutect2, pindel, varscan2
- IGSF11 | c.770_771insT p.I258Hfs*16 (on ENST00000393775 / NM_001015887.3; = p.I257Hfs*16 on NM_152538.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 110/244 reads (45%) | called by mutect2, pindel*, varscan2
- IL3RA | c.227_236del p.C76Sfs*32 | Frame Shift Del (DEL) | VAF 63/374 reads (17%) | called by pindel, varscan2
- MED12 | c.533_534dup p.H179Dfs*42 | Frame Shift Ins (INS) | VAF 52/105 reads (50%) | called by mutect2, pindel, varscan2
- MRC1 | c.1021A>T p.K341* | Nonsense Mutation (SNP) | VAF 98/410 reads (24%) | called by muse, mutect2, varscan2
- MYO19 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- OR8G2P | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- RAB25 | c.556_590del p.R186Wfs*80 | Frame Shift Del (DEL) | VAF 16/150 reads (11%) | called by mutect2, pindel
- RB1 | c.714dup p.Y239Ifs*2 | Frame Shift Ins (INS) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.170A>C p.E57A | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- TRAV13-1 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 62/185 reads (34%) | called by muse, mutect2, varscan2
- A1CF | c.1089C>G p.A363= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV50972148, COSV50982796; called by muse, mutect2, varscan2
- AC008397.2 | c.792G>T p.R264= | Silent (SNP) | VAF 92/304 reads (30%) | catalogued as COSV53208300; called by muse, mutect2, varscan2
- AC100868.1 | c.819C>T p.I273= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs1173218185, COSV51846197; called by muse, mutect2, varscan2
- ACVR1C | c.1449T>C p.S483= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV54647773; called by muse, mutect2, varscan2
- ADAM19 | c.1752C>G p.P584= | Silent (SNP) | VAF 41/167 reads (25%) | catalogued as COSV57433996; called by muse, mutect2, varscan2
- ADGRA2 | c.771G>A p.V257= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV59445207; called by muse, mutect2, varscan2
- ADGRL3 | c.1452C>T p.D484= (on ENST00000506720 / NM_001322402.2; = p.D416= on NM_015236.6) | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV72269565; called by muse, mutect2
- ADPGK | c.705C>T p.L235= | Silent (SNP) | VAF 47/130 reads (36%) | catalogued as COSV61174503; called by muse, mutect2, varscan2
- AEN | c.252G>C p.L84= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV60429172, COSV60429728; called by muse, mutect2
- AKT1S1 | c.660G>A p.A220= (on ENST00000344175 / NM_001098633.4; = p.A240= on NM_032375.5) | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs1332625244, COSV59276730; called by muse, mutect2, varscan2
- ALDH3A1 | c.531C>G p.L177= | Silent (SNP) | VAF 38/133 reads (29%) | catalogued as COSV56735974; called by muse, mutect2, varscan2
- ANKRD11 | c.1875G>A p.E625= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as COSV56365300; called by muse, mutect2, varscan2
- ANKRD52 | c.2631G>A p.L877= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV57285646; called by muse, mutect2, varscan2
- AP1M2 | c.390C>T p.I130= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV51568242; called by muse, mutect2, varscan2
- APOB | c.1902T>C p.S634= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as COSV51942883; called by muse, mutect2, varscan2
- ARHGAP22 | c.819G>A p.V273= | Silent (SNP) | VAF 49/147 reads (33%) | catalogued as COSV50956992; called by muse, mutect2, varscan2
- ARID2 | c.3963A>T p.L1321= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV57609035; called by muse, mutect2, varscan2
- ATP10B | c.2193C>G p.A731= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs753968677, COSV100514625; called by muse, mutect2, varscan2
- ATRNL1 | c.3912C>T p.P1304= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV58098408; called by muse, mutect2, varscan2
- ATRX | c.75A>T p.S25= | Silent (SNP) | VAF 60/90 reads (67%) | catalogued as COSV64869911; called by muse, mutect2, varscan2
- B4GALT5 | c.33G>T p.P11= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100866975; called by muse, mutect2
- BCO1 | c.33A>G p.E11= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV50730795; called by muse, mutect2, varscan2
- BPIFB3 | c.381C>T p.C127= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV64957653; called by muse, mutect2
- C15orf39 | c.2307A>G p.G769= | Silent (SNP) | VAF 2/12 reads (17%) | catalogued as rs1477159097, COSV62297305; called by muse, mutect2
- C20orf85 | c.81G>A p.L27= | Silent (SNP) | VAF 132/266 reads (50%) | catalogued as COSV64519571; called by muse, mutect2, varscan2
- CACFD1 | c.234C>T p.F78= | Silent (SNP) | VAF 354/439 reads (81%) | catalogued as COSV52470871; called by muse, mutect2, varscan2
- CACNA2D4 | c.2832G>A p.S944= | Silent (SNP) | VAF 44/144 reads (31%) | catalogued as rs375441882; called by muse, mutect2, varscan2
- CACNG3 | c.798C>A p.T266= | Silent (SNP) | VAF 96/215 reads (45%) | catalogued as COSV50074036; called by muse, mutect2, varscan2
- CARD11 | c.2805G>C p.L935= | Silent (SNP) | VAF 81/131 reads (62%) | catalogued as COSV62755972; called by muse, mutect2, varscan2
- CCDC86 | c.594A>G p.P198= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV57125687; called by muse, mutect2
- CD70 | c.102C>G p.L34= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as COSV55566564; called by muse, mutect2, varscan2
- CDH9 | c.111A>T p.I37= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV99143056; called by muse, mutect2, varscan2
- CFAP65 | c.4809C>T p.C1603= | Silent (SNP) | VAF 33/136 reads (24%) | catalogued as COSV58559882, COSV58563382; called by muse, mutect2, varscan2
- CNKSR2 | c.2418G>T p.R806= | Silent (SNP) | VAF 33/50 reads (66%) | catalogued as COSV54260889; called by muse, mutect2, varscan2
- CNST | c.525A>G p.S175= | Silent (SNP) | VAF 61/259 reads (24%) | catalogued as COSV63620744; called by muse, mutect2, varscan2
- COL4A2 | c.4803G>T p.A1601= | Silent (SNP) | VAF 31/101 reads (31%) | catalogued as COSV64630647; called by muse, mutect2, varscan2
- CSMD2 | c.2685G>C p.S895= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV99588562; called by muse, mutect2, varscan2
- CYP2D6 | c.567C>T p.L189= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV62244648; called by muse, varscan2
- DENND3 | c.1623G>A p.L541= | Silent (SNP) | VAF 48/170 reads (28%) | catalogued as COSV52804226; called by muse, varscan2
- DHX16 | c.241C>A p.R81= | Silent (SNP) | VAF 132/470 reads (28%) | catalogued as COSV64581237; called by muse, mutect2, varscan2
- DIRAS3 | c.186C>T p.F62= | Silent (SNP) | VAF 52/174 reads (30%) | catalogued as COSV63970934; called by muse, mutect2, varscan2
- DIS3 | c.1650C>T p.S550= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV66707117; called by muse, mutect2, varscan2
- DMRT3 | c.285A>G p.P95= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV51906322; called by muse, mutect2, varscan2
- DNAH10 | c.1518G>A p.E506= (on ENST00000409039; = p.E445= on NM_207437.3) | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV68996745; called by muse, mutect2, varscan2
- DOCK4 | c.5178C>T p.I1726= | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as rs1563432366, COSV70239949; called by muse, mutect2, varscan2
- DOCK6 | c.2184C>T p.F728= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs765853988, COSV52948961; called by muse, mutect2
- DSCAM | c.3786G>T p.V1262= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1426241278, COSV101259747; called by muse, mutect2, varscan2
- E2F7 | c.1362G>A p.Q454= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV59741609; called by muse, mutect2, varscan2
- EPX | c.1740C>T p.L580= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as COSV56597820; called by muse, mutect2, varscan2
- ERICH3 | c.3804A>T p.L1268= | Silent (SNP) | VAF 59/175 reads (34%) | catalogued as COSV58611844; called by muse, mutect2, varscan2
- FAM169A | c.585G>C p.G195= | Silent (SNP) | VAF 5/101 reads (5%) | catalogued as COSV65846857; called by muse, mutect2
- FCGBP | c.840T>C p.H280= | Silent (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- GABRB1 | c.1122C>A p.I374= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as COSV54971062; called by muse, mutect2, varscan2
- GALR1 | c.258C>G p.L86= | Silent (SNP) | VAF 74/130 reads (57%) | catalogued as COSV55317587; called by muse, mutect2, varscan2
- GPATCH2L | c.796C>T p.L266= | Silent (SNP) | VAF 56/175 reads (32%) | catalogued as rs761718133, COSV55049651; called by muse, mutect2, varscan2
- GRAMD4 | c.153G>C p.L51= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV63031226; called by muse, mutect2
- GRIP1 | c.3006G>A p.L1002= (on ENST00000359742 / NM_001379345.1; = p.L950= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as rs1321446217, COSV54031612; called by muse, mutect2, varscan2
- H3C4 | c.168G>A p.Q56= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as rs1263235235, COSV61912132; called by muse, mutect2, varscan2
- HAVCR1 | c.939C>T p.V313= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as COSV59401421; called by muse, mutect2, varscan2
- HNRNPUL1 | c.453C>T p.T151= | Silent (SNP) | VAF 61/173 reads (35%) | catalogued as rs1439553997, COSV54564343; called by muse, mutect2, varscan2
- HOXA3 | c.360G>T p.P120= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs369217098, COSV57826647; called by muse, mutect2, varscan2
- HYOU1 | c.216G>C p.V72= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV68216589; called by muse, mutect2, varscan2
- IGSF8 | c.393C>T p.S131= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV58758583; called by muse, mutect2, varscan2
- KCTD5 | c.627G>T p.L209= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV57065369; called by muse, mutect2, varscan2
- KIAA1549 | c.3975C>T p.R1325= | Silent (SNP) | VAF 45/242 reads (19%) | catalogued as COSV99650425; called by muse, mutect2, varscan2
- KLRD1 | c.150A>T p.I50= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as COSV60274182; called by muse, mutect2, varscan2
- KMT2C | c.2754T>C p.A918= | Silent (SNP) | VAF 40/264 reads (15%) | catalogued as COSV51464342; called by muse, mutect2, varscan2
- KPTN | c.405G>A p.L135= | Silent (SNP) | VAF 75/234 reads (32%) | catalogued as COSV54550188; called by muse, mutect2, varscan2
- KRT3 | c.549C>A p.L183= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV58816248; called by muse, mutect2, varscan2
- KRT75 | c.420C>A p.P140= | Silent (SNP) | VAF 47/175 reads (27%) | catalogued as COSV99359328; called by muse, mutect2, varscan2
- LIPH | c.531C>G p.L177= | Silent (SNP) | VAF 42/78 reads (54%) | catalogued as COSV56183200; called by muse, mutect2, varscan2
- LRP1 | c.2667C>G p.L889= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV54500824, COSV54517508; called by muse, mutect2, varscan2
- MAP3K12 | c.2226G>C p.L742= | Silent (SNP) | VAF 73/220 reads (33%) | catalogued as COSV57234186; called by muse, mutect2, varscan2
- MCM3AP | c.3636C>T p.V1212= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV52442238; called by muse, mutect2, varscan2
- MTCL1 | c.3888C>T p.P1296= (on ENST00000306329 / NM_001378206.1; = p.P977= on NM_015210.4) | Silent (SNP) | VAF 49/164 reads (30%) | catalogued as COSV60408501; called by muse, mutect2, varscan2
- MUC16 | c.41490C>T p.F13830= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as COSV66694483; called by muse, varscan2
- MUC16 | c.32496C>T p.S10832= | Silent (SNP) | VAF 52/159 reads (33%) | catalogued as rs773518499, COSV67478359; called by muse, mutect2
- NAB2 | c.282C>T p.L94= | Silent (SNP) | VAF 65/169 reads (38%) | catalogued as rs1310734457, COSV55666996; called by muse, mutect2, varscan2
- NAV2 | c.7122C>T p.V2374= (on ENST00000396087 / NM_001244963.2; = p.V2315= on NM_145117.5) | Silent (SNP) | VAF 69/207 reads (33%) | catalogued as COSV60661659; called by muse, mutect2, varscan2
- NSUN7 | c.1551G>C p.V517= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as COSV55956668; called by muse, mutect2
- NUF2 | c.207G>C p.V69= | Silent (SNP) | VAF 62/120 reads (52%) | catalogued as COSV54844980; called by muse, mutect2, varscan2
- NYAP2 | c.597G>C p.P199= | Silent (SNP) | VAF 61/181 reads (34%) | catalogued as COSV56003344, COSV56006863, COSV56010363; called by muse, mutect2, varscan2
- OR14C36 | c.597C>A p.V199= | Silent (SNP) | VAF 29/124 reads (23%) | catalogued as COSV58602040; called by muse, mutect2, varscan2
- OR4A16 | c.411G>C p.L137= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV59041842; called by muse, mutect2, varscan2
- OR51B2 | c.249A>G p.L83= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as rs189784581, COSV60917118; called by muse, mutect2, varscan2
- OR8G2P | c.570C>A p.S190= | Silent (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- PCM1 | c.417G>A p.K139= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1448812309, COSV61517723; called by muse, mutect2, varscan2
- PDIA2 | c.871C>A p.R291= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV51989611; called by muse, mutect2, varscan2
- PIGT | c.804C>T p.L268= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as COSV54127352; called by muse, mutect2, varscan2
- PLIN5 | c.276C>T p.L92= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as rs746004625, COSV67850500; called by muse, mutect2, varscan2
- PLPPR3 | c.819C>A p.I273= (on ENST00000520876 / NM_001270366.2; = p.I301= on NM_024888.2) | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV62460915; called by muse, mutect2, varscan2
- PLXNB2 | c.780G>A p.L260= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV63783034; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.150G>A p.Q50= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV57966739; called by muse, varscan2
- POLQ | c.30G>A p.R10= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV51756488; called by muse, mutect2, varscan2
- POLR1C | c.849C>T p.F283= | Silent (SNP) | VAF 37/128 reads (29%) | catalogued as rs1561858567, COSV54832279; called by muse, mutect2, varscan2
- PRKRIP1 | c.429G>A p.K143= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV61350298; called by muse, mutect2, varscan2
- PSMB1 | c.486C>T p.S162= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV51531252; called by muse, mutect2, varscan2
- RELN | c.696C>T p.G232= | Silent (SNP) | VAF 62/146 reads (42%) | catalogued as COSV59016682; called by muse, mutect2, varscan2
- RYR2 | c.5772C>A p.A1924= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV63697542; called by muse, mutect2, varscan2
- SATB1 | c.1560A>C p.A520= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as COSV58671065; called by muse, mutect2, varscan2
- SCN1A | c.1371A>G p.A457= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV57677433; called by muse, mutect2, varscan2
- SEMA3F | c.1620C>T p.V540= | Silent (SNP) | VAF 43/127 reads (34%) | catalogued as COSV50031822; called by muse, mutect2, varscan2
- SIK2 | c.1974C>T p.V658= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as COSV59254106; called by muse, mutect2, varscan2
- SIPA1L2 | c.3571C>T p.L1191= | Silent (SNP) | VAF 99/415 reads (24%) | catalogued as rs181504085, COSV53394261; called by muse, mutect2, varscan2
- SIRPB2 | c.981C>T p.G327= | Silent (SNP) | VAF 45/168 reads (27%) | catalogued as COSV63124471; called by muse, mutect2, varscan2
- SLC35G3 | c.714C>A p.L238= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV52011919; called by muse, mutect2, varscan2
- SLC4A4 | c.417A>G p.E139= (on ENST00000264485 / NM_001098484.3; = p.E95= on NM_003759.4) | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV52629862; called by muse, mutect2, varscan2
- SLCO1C1 | c.1191C>T p.L397= | Silent (SNP) | VAF 30/49 reads (61%) | catalogued as rs1174987494, COSV56875696; called by muse, mutect2, varscan2
- SSTR5 | c.651C>T p.I217= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV53512757; called by muse, mutect2, varscan2
- ST14 | c.912C>T p.T304= | Silent (SNP) | VAF 96/294 reads (33%) | catalogued as COSV53834666; called by muse, mutect2, varscan2
- STAB2 | c.1944G>A p.L648= | Silent (SNP) | VAF 63/114 reads (55%) | catalogued as COSV66342339; called by muse, mutect2, varscan2
- SULF2 | c.2439G>A p.L813= | Silent (SNP) | VAF 35/187 reads (19%) | catalogued as COSV59070667; called by muse, mutect2, varscan2
- TBC1D9 | c.2097C>T p.F699= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as COSV71307947; called by muse, mutect2, varscan2
- TCL1A | c.60C>A p.A20= | Silent (SNP) | VAF 50/154 reads (32%) | catalogued as COSV101268456; called by muse, mutect2, varscan2
- TFAP2D | c.324G>T p.G108= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV50431799, COSV99148481; called by muse, mutect2, varscan2
- THEMIS | c.1146C>A p.S382= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV64072401, COSV64072792; called by muse, mutect2, varscan2
- TMEM225 | c.561T>C p.S187= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs148160664; called by muse, mutect2
- TNFRSF1B | c.609G>T p.T203= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV66164380, COSV66164651; called by muse, mutect2
- TRANK1 | c.4323C>T p.F1441= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as rs775218539, COSV57156051; called by muse, mutect2, varscan2
- TRIM54 | c.84C>T p.I28= | Silent (SNP) | VAF 155/445 reads (35%) | catalogued as COSV56080692; called by muse, mutect2, varscan2
- TRPA1 | c.3141G>A p.Q1047= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV51565655, COSV51566876; called by muse, mutect2, varscan2
- TRPM3 | c.351C>A p.L117= (on ENST00000357533 / NM_001366142.2; = p.L86= on NM_001007471.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as COSV62471939; called by muse, mutect2, varscan2
- TRPV1 | c.2022C>T p.L674= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV51520978; called by muse, mutect2, varscan2
- TTBK1 | c.2949C>T p.L983= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs749572034, COSV52493772; called by muse, mutect2, varscan2
- TTI1 | c.2898C>T p.I966= | Silent (SNP) | VAF 59/215 reads (27%) | catalogued as COSV65062413; called by muse, mutect2, varscan2
- TTN | c.69558T>A p.T23186= (on ENST00000591111; = p.T15762= on NM_003319.4) | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV100610912, COSV60180289; called by muse, mutect2, varscan2
- TTN | c.4560C>A p.A1520= (on ENST00000591111; = p.A1474= on NM_003319.4) | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs1554009279, COSV60180325; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBGCP6 | c.1230G>C p.L410= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV50558950; called by muse, mutect2, varscan2
- ULK2 | c.2415C>T p.L805= | Silent (SNP) | VAF 98/153 reads (64%) | catalogued as COSV64446794; called by muse, mutect2, varscan2
- UPK1B | c.321C>T p.I107= | Silent (SNP) | VAF 105/247 reads (43%) | catalogued as COSV51767937; called by muse, mutect2, varscan2
- USF3 | c.5484C>T p.L1828= | Silent (SNP) | VAF 47/201 reads (23%) | catalogued as COSV100325343, COSV57074916; called by muse, mutect2, varscan2
- USH2A | c.13047C>A p.I4349= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV56397379, COSV56451581; called by muse, mutect2, varscan2
- USH2A | c.5715C>T p.S1905= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV56397409; called by muse, mutect2, varscan2
- ZNF157 | c.345C>G p.L115= | Silent (SNP) | VAF 38/63 reads (60%) | catalogued as COSV65659248; called by muse, mutect2, varscan2
- ZNF223 | c.342T>C p.P114= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV71571968; called by muse, mutect2, varscan2
- ZNF528 | c.189G>A p.K63= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV64620240; called by muse, mutect2, varscan2
- ABHD17B | chr9:71862582 C>A | 3'Flank (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100330187; called by muse, varscan2
- CARMIL3 | chr14:24048210 G>C | 5'Flank (SNP) | VAF 10/44 reads (23%) | catalogued as rs1409183479; called by muse, mutect2, varscan2
- LCMT1 | c.114-2377A>T | Intron (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- LEXM | c.1185-172T>C | Intron (SNP) | VAF 38/116 reads (33%) | catalogued as rs1557800852, COSV100827559; called by muse, mutect2, varscan2
- LINC02870 | n.289G>A | RNA (SNP) | VAF 60/263 reads (23%) | catalogued as rs1207554580; called by muse, mutect2, varscan2
- MIR205 | chr1:209430465 del C | 5'Flank (DEL) | VAF 61/196 reads (31%) | called by mutect2, pindel, varscan2
- TAF8 | chr6:42048611 G>C | 5'Flank (SNP) | VAF 10/24 reads (42%) | catalogued as COSV65895870; called by muse, mutect2, varscan2
- UPB1 | c.364+278G>A | Intron (SNP) | VAF 134/208 reads (64%) | catalogued as COSV100387142; called by muse, mutect2, varscan2
